Gene-level copy-number profile of tumor specimen TCGA-05-4427-01A from TCGA case TCGA-05-4427, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.4 years (23,893 days).
Specimen TCGA-05-4427-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7c026165-ad10-4cb4-ba8c-86b11403b3ed.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-05-4427-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f929f9e-c31c-410d-bf6d-efd3158eb987

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 5,594; copy number 3: 7,509; copy number 4: 12,662; copy number 5: 19,881; copy number 6: 9,443; copy number 7: 3,522; copy number 8: 526; copy number 9: 208; copy number 11: 467.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-05-4427-01A-21D-1854-01): tumor purity 0.47, ploidy 4.77, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 467 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,018,671–157,237,136, 452 genes, copy number 11 (broad region; genes not listed).
- chr6:58,386,799–62,286,225, 12 genes, copy number 11 (within-gene range 5–11): AL603755.1, AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.
- chr14:36,298,564–36,320,637, 1 gene, copy number 11: MBIP.
- chr14:36,371,165–36,405,274, 2 genes, copy number 11: DPPA3P2, RNU7-93P.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
